Somatic mutation profile of tumor specimen TCGA-DC-6681-01A (aliquot TCGA-DC-6681-01A-11D-1826-10) from TCGA case TCGA-DC-6681, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Age at diagnosis: 70.3 years (25,659 days).
Specimen TCGA-DC-6681-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf156698-cff0-4354-9849-95324f7428a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DC-6681-10A (Blood Derived Normal), aliquot TCGA-DC-6681-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17e45edf-b6b4-48e7-8ffd-ad80fbc57f9d

The open-access MAF lists 77 somatic variants for this specimen: 56 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 18, Nonsense Mutation 6, Frame Shift Ins 4, RNA 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, mutect2
- APC | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as rs775126020, CM980087, COSV57320525; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 34/117 reads (29%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 28/132 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- SMAD4 | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 21/55 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121912580, CM021284, COSV61684421, COSV61688134, COSV61692671; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.2004G>T p.W668C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58052681; called by muse, mutect2, varscan2
- APOL6 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as rs775222843, COSV68749572; called by muse, mutect2
- APP | c.2185A>G p.T729A | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61000336; called by muse, mutect2, varscan2
- ASXL1 | c.3195G>A p.W1065* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV60104380; called by muse, mutect2, varscan2
- ATP10A | c.2903G>A p.R968H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs150976669; called by muse, mutect2, varscan2
- ATP6V1B1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as COSV52266336; called by muse, mutect2, varscan2
- AUTS2 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs139132240, COSV100719209; called by muse, mutect2, varscan2
- AUTS2 | c.1694A>C p.D565A | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV61412680; called by muse, mutect2, varscan2
- BMP10 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.328); catalogued as rs777986452, COSV54893960; called by muse, mutect2
- CASP8AP2 | c.5822G>A p.C1941Y | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52748135; called by muse, mutect2, varscan2
- CD163 | c.3361G>T p.A1121S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV63134247; called by muse, mutect2, varscan2
- CD1D | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777157013, COSV63808414; called by muse, mutect2, varscan2
- CDC7 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52311241; called by muse, mutect2, varscan2
- CHST3 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215036898, CM106004, COSV64151196; called by muse, mutect2, varscan2
- DOCK3 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1325377187, COSV56530671; called by muse, mutect2, varscan2
- DRD5 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.234); catalogued as rs757838962, COSV58577799; called by muse, mutect2, varscan2
- ESR1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753014570, COSV52781671, COSV52788391; called by muse, mutect2, varscan2
- FAM83C | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as rs752621565, COSV65582636; called by muse, mutect2, varscan2
- FANCM | c.5228C>G p.S1743C | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as COSV57502727; called by muse, mutect2, varscan2
- FRMD5 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.078); catalogued as rs551307319, COSV68723181; called by muse, mutect2, varscan2
- GCM1 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV52522503; called by muse, mutect2, varscan2
- GPR158 | c.1592C>A p.A531E | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV66280848, COSV66285447; called by muse, mutect2, varscan2
- GRIA2 | c.1003G>C p.A335P | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.91); catalogued as COSV52395459; called by muse, mutect2, varscan2
- GRM3 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1385120633, COSV64474356; called by muse, mutect2, varscan2
- GTF3C2 | c.404T>G p.L135R | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.462); catalogued as COSV53127375; called by muse, mutect2, varscan2
- HERC2 | c.4496G>A p.G1499D | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs763287026, COSV99870323; called by muse, mutect2
- HTR7 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.89); catalogued as rs1259010208, COSV53290260; called by muse, mutect2
- IFRD1 | c.1249A>G p.I417V | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.163); catalogued as COSV50044475; called by muse, mutect2, varscan2
- JAKMIP1 | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV68950764, COSV68952032; called by muse, mutect2, varscan2
- KIAA1549L | c.3511C>T p.P1171S (on ENST00000321505; = p.P1468S on NM_012194.3) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs558721492, COSV55773405, COSV55776193; called by muse, mutect2, varscan2
- KIRREL3 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs747117945, COSV73106841; called by muse, mutect2, varscan2
- KRTAP10-8 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV58166017, COSV58166627; called by muse, mutect2
- NAALADL1 | c.1594G>C p.D532H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60524620; called by muse, mutect2, varscan2
- NOTCH4 | c.3239A>G p.E1080G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.141); catalogued as COSV100900495; called by muse, mutect2, varscan2
- OR10H5 | c.203T>C p.I68T | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV58278473; called by muse, mutect2, varscan2
- OR2B2 | c.181_182insG p.F61Cfs*4 | Frame Shift Ins (INS) | VAF 20/72 reads (28%) | catalogued as COSV57580001; called by mutect2, pindel, varscan2
- PCDHGA5 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53974388; called by muse, mutect2, varscan2
- PDHA2 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs750043606, COSV54779955, COSV54780252; called by muse, mutect2, varscan2
- PRICKLE2 | c.805C>T p.R269* (on ENST00000295902; = p.R213* on NM_198859.4) | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as rs753970642, COSV55767918; called by muse, mutect2, varscan2
- RAB41 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.007); catalogued as rs746401277, COSV52103470; called by muse, mutect2, varscan2
- RELN | c.4439G>C p.G1480A | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV100632886; called by muse, mutect2, varscan2
- SERPINA4 | c.1040A>G p.D347G | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.791); catalogued as COSV54070544; called by muse, mutect2, varscan2
- SLC30A3 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51986271; called by muse, mutect2, varscan2
- SPAG6 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57621518; called by muse, mutect2, varscan2
- SPTBN5 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs759525342, COSV58019633; called by muse, mutect2, varscan2
- TCF7L2 | c.1162T>C p.W388R (on ENST00000355995 / NM_001367943.1; = p.W365R on NM_030756.5) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53342817; called by muse, mutect2
- TMPRSS6 | c.1036T>C p.Y346H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV60980306; called by muse, mutect2, varscan2
- UBE4B | c.3346C>T p.R1116* (on ENST00000343090 / NM_001105562.3; = p.R987* on NM_006048.5) | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as rs1478970742, COSV53535024; called by muse, mutect2, varscan2
- PPCS | c.336_337dup p.S113Ffs*5 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- PUM1 | c.1158+1del p.X386_splice | Splice Site (DEL) | VAF 30/79 reads (38%) | called by mutect2, pindel, varscan2
- SOX9 | c.700_701dup p.P235Hfs*19 | Frame Shift Ins (INS) | VAF 52/192 reads (27%) | called by pindel, varscan2
- ABCA4 | c.2790C>T p.C930= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs756961160, COSV64674714; called by muse, mutect2, varscan2
- ADAMTS12 | c.2766G>A p.P922= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV61262850, COSV61263240; called by muse, mutect2, varscan2
- APBA3 | c.1050C>T p.A350= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs367941981; called by mutect2, varscan2
- CFAP61 | c.3243G>A p.A1081= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1472296292, COSV55620127; called by muse, mutect2, varscan2
- DOCK8 | c.5004C>T p.A1668= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs770069467, COSV66621231; called by muse, mutect2, varscan2
- FSTL4 | c.22C>T p.L8= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV54775613; called by muse, mutect2, varscan2
- GLUD2 | c.1176C>T p.N392= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as rs1242855174, COSV60151317; called by muse, mutect2, varscan2
- GRK7 | c.1482G>A p.G494= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as COSV53822107, COSV53823680; called by muse, mutect2, varscan2
- HSPBP1 | c.885C>T p.A295= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1274960646, COSV99728995; called by muse, mutect2
- IGF1R | c.1446C>T p.N482= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs537098180, COSV51306109; called by muse, mutect2, varscan2
- IGHA1 | c.819C>T p.R273= | Silent (SNP) | VAF 56/324 reads (17%) | catalogued as rs778291607; called by muse, varscan2
- IL17REL | c.570G>A p.A190= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV58008465; called by muse, mutect2, varscan2
- INHBA | c.546G>A p.P182= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs141733287, COSV54222714; called by muse, mutect2, varscan2
- PCDHGB1 | c.21C>T p.A7= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs1248847691, COSV53974368; called by muse, mutect2, varscan2
- PITPNM2 | c.3453G>A p.T1151= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs746076618, COSV54903223; called by muse, mutect2, varscan2
- PPP1R15A | c.1506T>C p.A502= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99565914; called by muse, mutect2, varscan2
- SLC16A1 | c.594C>T p.I198= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as rs755634416, COSV63709654; called by muse, mutect2
- VPS37C | c.996C>T p.P332= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100075114; called by muse, mutect2, varscan2
- ARPP21 | c.2032+530C>T | Intron (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99491413; called by muse, mutect2
- FRMPD2B | n.1321A>T | RNA (SNP) | VAF 34/160 reads (21%) | called by mutect2, varscan2
- FRMPD2B | n.1322C>T | RNA (SNP) | VAF 35/159 reads (22%) | called by mutect2, varscan2
